Somatic mutation profile of tumor specimen TCGA-AX-A0J1-01A (aliquot TCGA-AX-A0J1-01A-11W-A062-09) from TCGA case TCGA-AX-A0J1, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 80.8 years (29,501 days).
Specimen TCGA-AX-A0J1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d35a262-39b2-4ce8-872a-24591fc4609b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A0J1-10A (Blood Derived Normal), aliquot TCGA-AX-A0J1-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f03292ba-467a-4cad-a0cc-6d342ee0af38

The open-access MAF lists 6,402 somatic variants for this specimen: 4,653 protein-altering or splice-affecting, 1,612 silent, 137 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,994, Silent 1,612, Nonsense Mutation 249, Frame Shift Del 221, Frame Shift Ins 73, Intron 64, Splice Site 60, Splice Region 50, RNA 38, 3'UTR 15, 3'Flank 9, 5'Flank 7.

Variants (750 of 6,402; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADNP | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 71/158 reads (45%) | catalogued as rs1057518991, COSV62426779; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADSL | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs796052248, COSV53411299; ClinVar: pathogenic; called by muse, mutect2
- APOB | c.7564C>T p.R2522* | Nonsense Mutation (SNP) | VAF 70/272 reads (26%) | catalogued as rs121918390, CM920059, COSV51950425, COSV51957062; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.8545C>T p.R2849* | Nonsense Mutation (SNP) | VAF 135/507 reads (27%) | catalogued as rs587778080, CM990221, COSV53771567; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ATM | c.8977C>T p.R2993* | Nonsense Mutation (SNP) | VAF 45/368 reads (12%) | catalogued as rs770641163, CM960113, COSV53732836; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel
- BRCA2 | c.5073del p.K1691Nfs*15 | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | catalogued as rs80359479; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- COL4A5 | c.2821G>T p.G941C | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886196, CM983309, COSV60370800; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COPB2 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs1229568621, COSV60813766; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CSF1R | c.2320-2A>G p.X774_splice | Splice Site (SNP) | VAF 19/77 reads (25%) | catalogued as rs281860272, CS1111007, COSV53842254; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CYP27A1 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 114/388 reads (29%) | catalogued as rs72551318, CM003737; ClinVar: pathogenic; called by muse, varscan2
- DNAH11 | c.13069C>T p.R4357* | Nonsense Mutation (SNP) | VAF 30/224 reads (13%) | catalogued as rs775720394, COSV60978335; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EIF1AX | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 78/253 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.693); catalogued as COSV63309291, COSV63309392, COSV63309466; called by muse, mutect2, varscan2
- FGD4 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs281865063, CM125801, COSV56788937; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- HNF1A | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 21/54 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs774996577, CM093340, COSV57466577; called by muse, mutect2, varscan2
- INVS | c.2719C>T p.R907* | Nonsense Mutation (SNP) | VAF 36/109 reads (33%) | catalogued as rs267607185, CM032003, COSV52449170; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ3 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749205120, COSV101196319, COSV66465699; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- LPL | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs118204062, CM910265, CM962613, COSV100255676; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NAA15 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 18/272 reads (7%) | catalogued as rs1274633498, COSV56719543; ClinVar: pathogenic; called by muse, mutect2
- NF1 | c.5609G>A p.R1870Q (on ENST00000358273 / NM_001042492.3; = p.R1849Q on NM_000267.3) | Missense Mutation (SNP) | VAF 43/132 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs786202112, CM1411401, CS000055, CS1311534, CS1311535, COSV62210316; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHS2 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs74315348, CM000585, COSV62634844; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 278/389 reads (71%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RPGRIP1 | c.2668C>T p.R890* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as rs780587095, CM012462, COSV52856448; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SDHB | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138996609, CM034573, COSV64965126; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SEC23B | c.1588C>T p.R530W | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918223, CM094611, COSV52723475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SERPINC1 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 64/326 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487411568, CM063131, CM921005, COSV62930399, COSV62930470; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- SIN3A | c.3310C>T p.R1104* | Nonsense Mutation (SNP) | VAF 31/84 reads (37%) | catalogued as rs879255621, COSV64581642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAT5B | c.1102del p.Q368Rfs*2 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TGFBR1 | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869025535, COSV66625357, COSV66626886; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TUBGCP6 | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.811); catalogued as rs1444741505, COSV50542723; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.10450C>T p.R3484* | Nonsense Mutation (SNP) | VAF 36/227 reads (16%) | catalogued as rs111033379, CM080610, COSV56427899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ZNF649 | c.593G>T p.R198I | Missense Mutation (SNP) | VAF 108/350 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs373638440, COSV56814561; called by muse, mutect2, varscan2
- A2ML1 | c.483G>T p.Q161H | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs773313620, COSV55297737; called by muse, mutect2, varscan2
- AACS | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as rs1259992246, COSV55537442; called by muse, varscan2
- AANAT | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs765693283, COSV51686213; called by muse, mutect2, varscan2
- ABAT | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV51627827; called by muse, mutect2, varscan2
- ABCA12 | c.5236G>T p.G1746C (on ENST00000272895 / NM_173076.3; = p.G1428C on NM_015657.3) | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55973693; called by muse, mutect2, varscan2
- ABCA12 | c.2123C>T p.A708V (on ENST00000272895 / NM_173076.3; = p.A390V on NM_015657.3) | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs756116447, COSV55973711; called by muse, mutect2, varscan2
- ABCA13 | c.9607G>A p.V3203I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs563077060, COSV71293575; called by muse, mutect2, varscan2
- ABCA13 | c.13570G>A p.A4524T | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1163099421, COSV68948669; called by muse, mutect2, varscan2
- ABCA3 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as rs1278044377, CM040355, COSV57059294; called by muse, mutect2, varscan2
- ABCA4 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs754088610, COSV64677416; called by muse, mutect2, varscan2
- ABCA5 | c.742del p.I248* | Frame Shift Del (DEL) | VAF 14/123 reads (11%) | catalogued as rs751460805, COSV67017665; called by mutect2, varscan2
- ABCA6 | c.2525G>A p.R842Q | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); catalogued as rs1307761237, COSV52642738; called by muse, mutect2, varscan2
- ABCA8 | c.3875C>T p.S1292F | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV52210868; called by muse, mutect2, varscan2
- ABCA8 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52210886; called by muse, mutect2, varscan2
- ABCA9 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs780668341, COSV60622997; called by muse, mutect2, varscan2
- ABCB1 | c.2369A>G p.Y790C | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.945); catalogued as COSV99713655; called by muse, mutect2
- ABCB1 | c.2263T>C p.F755L | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.568); catalogued as COSV55962205; called by muse, mutect2
- ABCB10 | c.1533G>T p.Q511H | Missense Mutation (SNP) | VAF 96/562 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV60623510; called by muse, varscan2
- ABCB11 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1384540976, COSV55599979; called by muse, mutect2, varscan2
- ABCB5 | c.3002G>A p.R1001H (on ENST00000404938 / NM_001163941.2; = p.R556H on NM_178559.6) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs528761902, COSV51716155; called by mutect2, varscan2
- ABCB5 | c.3299C>T p.P1100L (on ENST00000404938 / NM_001163941.2; = p.P655L on NM_178559.6) | Missense Mutation (SNP) | VAF 80/278 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as rs1211271086, COSV51719870; called by muse, varscan2
- ABCB6 | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765195871, COSV54695466; called by muse, mutect2, varscan2
- ABCB7 | c.1744G>A p.A582T (on ENST00000373394 / NM_001271696.3; = p.A583T on NM_004299.6) | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV53723229; called by muse, mutect2, varscan2
- ABCC1 | c.2326G>A p.V776M | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as rs763781150, COSV60693286; called by muse, mutect2, varscan2
- ABCC11 | c.1928G>A p.S643N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV62325625; called by muse, mutect2, varscan2
- ABCC2 | c.1769G>A p.R590H | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751940502, COSV64986658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC4 | c.2491C>T p.H831Y | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV65317824; called by muse, mutect2, varscan2
- ABCC9 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.046); catalogued as rs772619542, COSV53980351; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCD2 | c.261G>T p.Q87H | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as rs1390785264, COSV58054737; called by muse, mutect2, varscan2
- ABCF1 | c.2246C>T p.A749V (on ENST00000326195 / NM_001025091.2; = p.A711V on NM_001090.3) | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777572931, COSV58227852; called by muse, mutect2, varscan2
- ABCF2 | c.1840C>A p.P614T | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV99734682; called by muse, varscan2
- ABCF2 | c.1778A>G p.K593R | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.028); catalogued as COSV55186383; called by muse, varscan2
- ABCG1 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs766235564, COSV59200653; called by muse, mutect2, varscan2
- ABCG1 | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV59209860; called by muse, mutect2, varscan2
- ABHD12 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs991573752, COSV53822487; called by muse, mutect2, varscan2
- ABHD15 | c.1210A>G p.S404G | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as COSV56196598; called by muse, mutect2, varscan2
- ABL1 | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 18/188 reads (10%) | catalogued as COSV59340385; called by muse, mutect2
- ABL2 | c.545C>T p.A182V (on ENST00000502732 / NM_007314.4; = p.A167V on NM_005158.5) | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV61020158; called by muse, mutect2, varscan2
- AC004922.1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV53559078; called by muse, mutect2, varscan2
- AC100868.1 | c.2050G>A p.G684R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs746236844, COSV51849310; called by muse, mutect2, varscan2
- AC126283.2 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 120/440 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367677199, CM100540; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC127029.3 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as rs371051668, COSV60111188; called by mutect2, varscan2
- AC144573.1 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious, low confidence (0); catalogued as COSV56877507; called by muse, mutect2, varscan2
- AC253536.7 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs537065055, COSV53159721; called by muse, mutect2
- ACAA1 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 41/106 reads (39%) | catalogued as rs755191918, COSV57179702; called by muse, mutect2, varscan2
- ACACB | c.7079G>A p.R2360H | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs750093564, COSV58144993; called by muse, mutect2, varscan2
- ACAD11 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as rs544486722, COSV53894996; called by muse, mutect2, varscan2
- ACAD8 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55540023; called by muse, mutect2, varscan2
- ACAD9 | c.1521C>A p.C507* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV58309767; called by muse, mutect2, varscan2
- ACADM | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.633); catalogued as COSV63720997; called by muse, mutect2, varscan2
- ACAN | c.5143C>A p.L1715I | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.992); catalogued as COSV100718733; called by muse, mutect2
- ACAP1 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 83/188 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1017836179, COSV50141203; called by muse, mutect2, varscan2
- ACAP2 | c.1720G>T p.E574* | Nonsense Mutation (SNP) | VAF 12/150 reads (8%) | catalogued as COSV100462502; called by muse, mutect2
- ACBD7 | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV62252866; called by muse, mutect2, varscan2
- ACE | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774394975, COSV52012647; called by mutect2, varscan2
- ACER1 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs757612469, COSV56836810; called by muse, mutect2, varscan2
- ACIN1 | c.3754C>T p.R1252* | Nonsense Mutation (SNP) | VAF 29/95 reads (31%) | catalogued as COSV52981646; called by muse, mutect2, varscan2
- ACLY | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as rs541819037; called by muse, mutect2
- ACMSD | c.274C>A p.L92M | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.75); catalogued as COSV99299320; called by muse, mutect2
- ACMSD | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51609384; called by muse, mutect2, varscan2
- ACMSD | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs766223313, COSV51609389; called by muse, mutect2, varscan2
- ACO1 | c.1922C>T p.T641M | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770368084, COSV59377291; called by muse, mutect2, varscan2
- ACO2 | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.3); catalogued as COSV53445151; called by muse, mutect2, varscan2
- ACOT13 | c.212C>A p.A71D | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100016060; called by muse, mutect2, varscan2
- ACP6 | c.1236C>A p.Y412* | Nonsense Mutation (SNP) | VAF 122/637 reads (19%) | catalogued as COSV65077898; called by muse, mutect2, varscan2
- ACRBP | c.1533G>T p.Q511H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV57525232; called by muse, mutect2, varscan2
- ACSBG1 | c.1771C>A p.L591M | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV51910241; called by muse, mutect2, varscan2
- ACSL4 | c.1421C>A p.A474D (on ENST00000340800 / NM_022977.2; = p.A433D on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/341 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61615708; called by muse, mutect2, varscan2
- ACTBL2 | c.826C>A p.H276N | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.566); catalogued as COSV70661717; called by muse, mutect2, varscan2
- ACTL8 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs924872941, COSV64862530; called by muse, mutect2, varscan2
- ACTL9 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as rs376851453; called by muse, mutect2, varscan2
- ACTR10 | c.347C>A p.P116Q | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV54299929; called by muse, varscan2
- ACTR1B | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs372634354; called by muse, mutect2, varscan2
- ACTR3 | c.589G>T p.G197* | Nonsense Mutation (SNP) | VAF 18/175 reads (10%) | catalogued as COSV99603828; called by muse, mutect2, varscan2
- ACVR1C | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 87/263 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54649489; called by muse, mutect2, varscan2
- ACVR2A | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV54028491; called by muse, varscan2
- ADAM2 | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV99697645; called by muse, mutect2, varscan2
- ADAM21 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs757545988, COSV50807470, COSV50807988; called by muse, mutect2, varscan2
- ADAM22 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.843); catalogued as COSV99717630; called by muse, mutect2
- ADAM28 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 26/275 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99739263; called by muse, mutect2, varscan2
- ADAMDEC1 | c.148C>A p.L50I | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); catalogued as COSV99836190; called by muse, mutect2
- ADAMTS1 | c.2822G>A p.G941E | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.405); catalogued as COSV53173144; called by muse, mutect2, varscan2
- ADAMTS10 | c.1655C>A p.P552Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.681); catalogued as COSV54359131, COSV99547550; called by muse, mutect2, varscan2
- ADAMTS13 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs370929256; called by muse, mutect2, varscan2
- ADAMTS16 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99942092; called by muse, mutect2, varscan2
- ADAMTS16 | c.3189C>A p.C1063* | Nonsense Mutation (SNP) | VAF 46/163 reads (28%) | catalogued as COSV57005609; called by muse, mutect2, varscan2
- ADAMTS17 | c.3265C>T p.R1089C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs765090779, COSV51472944; called by muse, varscan2
- ADAMTS17 | c.3211C>T p.R1071W | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773331594, COSV51492534; called by muse, varscan2
- ADAMTS3 | c.3215T>C p.V1072A | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54401417; called by muse, mutect2, varscan2
- ADAMTS3 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.679); catalogued as COSV99711652; called by muse, mutect2
- ADAMTS8 | c.1063C>T p.L355F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57297214; called by muse, mutect2, varscan2
- ADARB1 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV62347770; called by muse, mutect2, varscan2
- ADAT1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57188286; called by muse, mutect2, varscan2
- ADAT1 | c.474C>A p.C158* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV100329262; called by muse, mutect2
- ADCY1 | c.2537C>T p.A846V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52041630; called by muse, mutect2, varscan2
- ADCY1 | c.3215G>A p.R1072Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs775166558, COSV52035143; called by muse, mutect2, varscan2
- ADCY10 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 34/286 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.388); catalogued as COSV63244523; called by muse, mutect2, varscan2
- ADCY2 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs769674129, COSV57864636; called by muse, mutect2, varscan2
- ADCY2 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV57897081; called by muse, mutect2, varscan2
- ADCY5 | c.3772C>T p.P1258S | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV59203388, COSV59203714; called by muse, mutect2, varscan2
- ADCY5 | c.3650G>T p.R1217L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.689); catalogued as COSV59194442, COSV59203728; called by muse, mutect2, varscan2
- ADCY6 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.446); catalogued as rs755290608, COSV57169808; called by muse, varscan2
- ADCY6 | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.026); catalogued as COSV57170272; called by muse, varscan2
- ADCY7 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs754927240, COSV54270471; called by muse, mutect2, varscan2
- ADCY7 | c.827A>G p.Q276R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs200194609; called by mutect2, varscan2
- ADCY9 | c.1970A>T p.E657V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV53581148; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.042); catalogued as rs779140594, COSV58443459; called by muse, mutect2, varscan2
- ADD1 | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as COSV53273803; called by muse, mutect2, varscan2
- ADD1 | c.1660G>A p.V554I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs755498319, COSV53273817; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 58/239 reads (24%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA3 | c.2853G>T p.E951D | Missense Mutation (SNP) | VAF 98/349 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); catalogued as COSV51567751; called by muse, mutect2, varscan2
- ADGRB2 | c.4706C>T p.A1569V (on ENST00000373658 / NM_001364857.2; = p.A1568V on NM_001294335.2) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.044); catalogued as COSV57078335; called by muse, mutect2
- ADGRB3 | c.2944C>T p.R982C | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53236298; called by muse, mutect2, varscan2
- ADGRF1 | c.1720T>C p.S574P | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV51947484; called by muse, mutect2, varscan2
- ADGRF2 | c.1127G>T p.R376I (on ENST00000296862 / NM_001368115.2; = p.R308I on NM_153839.7) | Missense Mutation (SNP) | VAF 76/240 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs368691313, COSV57286389; called by muse, mutect2, varscan2
- ADGRG2 | c.2165C>T p.A722V (on ENST00000379869 / NM_001079858.3; = p.A719V on NM_005756.4) | Missense Mutation (SNP) | VAF 102/294 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61341069; called by muse, mutect2, varscan2
- ADGRG7 | c.1915A>G p.N639D | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56300837; called by muse, varscan2
- ADGRV1 | c.7529G>T p.W2510L | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.655); catalogued as COSV101316226; called by muse, mutect2
- ADGRV1 | c.8672G>A p.G2891D | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as COSV67994332; called by muse, mutect2, varscan2
- ADGRV1 | c.15230C>T p.T5077I | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV67994333; called by muse, mutect2, varscan2
- ADGRV1 | c.17930C>T p.T5977I | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV67994335; called by muse, mutect2, varscan2
- ADH6 | c.775A>T p.T259S | Missense Mutation (SNP) | VAF 212/715 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV52957670; called by muse, mutect2, varscan2
- ADH6 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs772312242, COSV52957685; called by muse, varscan2
- ADIPOR1 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 43/242 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs1163798454, COSV61852409; called by muse, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 56/167 reads (34%) | catalogued as rs761350619; called by mutect2, varscan2
- ADPRS | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.299); catalogued as COSV52882063; called by muse, mutect2, varscan2
- ADRB2 | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs1459780191, COSV60006198; called by muse, mutect2, varscan2
- ADSL | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 70/271 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV53410211; called by muse, mutect2, varscan2
- ADSL | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369617680, COSV53409693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADSS2 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 52/296 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs749437463, COSV63696109; called by muse, varscan2
- AEN | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756014603, COSV60430373; called by muse, mutect2, varscan2
- AFDN | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 176/503 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60055687; called by muse, mutect2, varscan2
- AFDN | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753394042, COSV100653086, COSV60055721; called by muse, mutect2, varscan2
- AFDN | c.4858C>T p.R1620C (on ENST00000447894 / NM_001366320.1; = p.R1618C on NM_001040000.3) | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV60039779; called by muse, mutect2
- AFF1 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 152/539 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768503856, COSV57123574; called by muse, mutect2, varscan2
- AFF2 | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 202/750 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60679777, COSV60682117; called by muse, mutect2, varscan2
- AFF2 | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 125/322 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1569557647, COSV53987444, COSV54005627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AFF2 | c.3914G>A p.R1305H | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as rs1041916973, COSV53990241, COSV53998281; called by muse, mutect2, varscan2
- AFF3 | c.3649C>T p.H1217Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as COSV57870472; called by muse, mutect2, varscan2
- AFG1L | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64558008; called by muse, mutect2, varscan2
- AFP | c.855G>A p.M285I | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV56926870; called by muse, mutect2, varscan2
- AGA | c.69C>A p.C23* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV52807533; called by muse, mutect2, varscan2
- AGAP1 | c.2075G>C p.S692T (on ENST00000304032 / NM_001037131.3; = p.S639T on NM_014914.5) | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.111); catalogued as COSV58338133; called by muse, mutect2, varscan2
- AGAP2 | c.1960C>T p.R654W (on ENST00000547588 / NM_001122772.2; = p.R318W on NM_014770.4) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1401941766, COSV57730554, COSV57731171; called by muse, mutect2, varscan2
- AGAP6 | c.1708C>T p.R570W (on ENST00000374056 / NM_001365867.1; = p.R593W on NM_001077665.2) | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs782163616; called by muse, mutect2, varscan2
- AGBL1 | c.1635G>T p.Q545H | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV66871290; called by muse, mutect2, varscan2
- AGBL1 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 124/359 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as rs376573682; called by muse, mutect2
- AGK | c.297+1G>A p.X99_splice | Splice Site (SNP) | VAF 46/150 reads (31%) | catalogued as rs374365225; called by muse, mutect2, varscan2
- AGK | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 117/296 reads (40%) | catalogued as COSV62595859; called by muse, mutect2, varscan2
- AGO3 | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 50/506 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99869051; called by muse, mutect2
- AGO4 | c.2390G>A p.R797H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1351075166, COSV100943024; called by muse, mutect2
- AGT | c.914G>A p.S305N | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs200008829, COSV64185479; called by muse, mutect2, varscan2
- AGTR2 | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 20/285 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1440815286, COSV100903558, COSV100903598; called by muse, mutect2
- AHCTF1 | c.1733A>T p.E578V (on ENST00000366508; = p.E552V on NM_015446.5) | Missense Mutation (SNP) | VAF 30/456 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100404089; called by muse, mutect2
- AHCYL2 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs754743825, COSV61486002; called by muse, mutect2, varscan2
- AHDC1 | c.2227C>T p.R743W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751160000, COSV55942078; called by muse, mutect2, varscan2
- AHNAK | c.2247G>A p.M749I | Missense Mutation (SNP) | VAF 119/285 reads (42%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.98); catalogued as COSV57228686; called by muse, varscan2
- AHRR | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773432660, COSV57088171; called by muse, mutect2, varscan2
- AIPL1 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs537788083, COSV51508826; called by muse, mutect2, varscan2
- AKAP11 | c.5377G>A p.D1793N | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as rs1004014247, COSV50301770; called by muse, mutect2, varscan2
- AKAP14 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 62/726 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV100538307, COSV100538360; called by muse, mutect2
- AKAP6 | c.3817T>C p.Y1273H | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99802625; called by muse, mutect2
- AKAP6 | c.5794C>T p.H1932Y | Missense Mutation (SNP) | VAF 78/247 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55231107; called by muse, mutect2, varscan2
- AKAP7 | c.618del p.G207Afs*4 | Frame Shift Del (DEL) | VAF 13/123 reads (11%) | catalogued as rs1250147982; called by mutect2, pindel
- AKAP9 | c.7643A>G p.D2548G (on ENST00000359028; = p.D2524G on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.405); catalogued as COSV100662711; called by muse, mutect2
- AKAP9 | c.11344C>T p.R3782C (on ENST00000359028; = p.R3758C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs779901993, COSV62338810; called by muse, mutect2, varscan2
- AKR1B15 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV101423394; called by muse, varscan2
- AKR1E2 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.123); catalogued as rs772663485, COSV53631417, COSV53631769; called by mutect2, varscan2
- AKT2 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs575460456, COSV60910194; called by mutect2, varscan2
- AKT3 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV55631050; called by muse, mutect2, varscan2
- AKT3 | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV55631084; called by muse, mutect2, varscan2
- AKTIP | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs781311887, COSV50886811; called by mutect2, varscan2
- AL441992.2 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs770205049, COSV56913694; called by muse, mutect2, varscan2
- AL592490.1 | c.2815C>T p.H939Y | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.038); catalogued as COSV69427700; called by muse, mutect2, varscan2
- AL592490.1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.089); catalogued as rs1414894279, COSV69427706; called by muse, varscan2
- ALAS1 | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1011583315, COSV59627343, COSV59627481; called by muse, mutect2, varscan2
- ALAS2 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58193068; called by muse, mutect2, varscan2
- ALAS2 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 70/364 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430414100, COSV58193081; called by muse, mutect2, varscan2
- ALDH1B1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs775731660, COSV66619652, COSV66619678; called by muse, mutect2, varscan2
- ALDH2 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs190764869, COSV55670977; called by muse, mutect2, varscan2
- ALDH3B2 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs748729064, COSV62429265; called by muse, mutect2, varscan2
- ALDH7A1 | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.94); catalogued as rs947628303; called by muse, mutect2
- ALDOB | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767812270, COSV66398262; called by mutect2, varscan2
- ALG13 | c.2354G>A p.G785D | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV99322640; called by muse, mutect2
- ALG8 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as rs140716983; called by muse, mutect2, varscan2
- ALKBH7 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755922067, COSV55532649, COSV55532815; called by muse, mutect2, varscan2
- ALMS1 | c.4298A>G p.E1433G | Missense Mutation (SNP) | VAF 21/268 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV100043133; called by muse, mutect2
- ALMS1 | c.6353T>C p.V2118A | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV52509243; called by muse, mutect2, varscan2
- ALOX12 | c.1718C>T p.T573M | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777885513, COSV52350954; called by muse, mutect2, varscan2
- ALOXE3 | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.119); catalogued as rs575594494, COSV59077733; called by muse, mutect2, varscan2
- ALPL | c.1439T>C p.V480A | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV100876202; called by muse, mutect2, varscan2
- ALS2CL | c.2600C>T p.T867M | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs74585038, COSV59674654; called by muse, mutect2, varscan2
- ALS2CL | c.1480G>A p.G494S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs140756490; called by mutect2, varscan2
- AMIGO2 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99873713; called by muse, mutect2
- AMMECR1 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs763040190, COSV53320051; called by muse, mutect2, varscan2
- AMOTL1 | c.329G>A p.G110D | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs748299534, COSV54418551; called by muse, mutect2, varscan2
- AMOTL1 | c.2582C>T p.T861M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.186); catalogued as rs764026403, COSV58570351; called by muse, mutect2, varscan2
- AMOTL2 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs369381825; called by muse, mutect2, varscan2
- AMOTL2 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.921); catalogued as rs569311001, COSV51440725; called by muse, mutect2, varscan2
- AMPD1 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 79/196 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs1211976677, COSV62415632; called by muse, mutect2, varscan2
- AMZ2 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs573816812, COSV100703195; called by muse, mutect2
- ANAPC1 | c.4747G>A p.A1583T | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs760585060, COSV61975107; called by muse, mutect2, varscan2
- ANAPC1 | c.1396C>T p.L466F | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV61979184; called by muse, mutect2, varscan2
- ANAPC1 | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100594934; called by muse, mutect2, varscan2
- ANK1 | c.3097C>A p.L1033I | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55894091, COSV99225886; called by muse, mutect2, varscan2
- ANK1 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.187); catalogued as rs377658590; called by muse, mutect2, varscan2
- ANK2 | c.902C>T p.T301I | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52185492; called by muse, mutect2, varscan2
- ANK2 | c.3322C>T p.H1108Y | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100002944; called by muse, mutect2
- ANKDD1A | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs553148491, COSV60353072; called by muse, mutect2, varscan2
- ANKFY1 | c.2392G>A p.A798T (on ENST00000341657 / NM_001330063.2; = p.A799T on NM_016376.5) | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs1405815867, COSV58922185; called by muse, mutect2, varscan2
- ANKFY1 | c.2165G>A p.G722D (on ENST00000341657 / NM_001330063.2; = p.G723D on NM_016376.5) | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV58922199; called by muse, mutect2, varscan2
- ANKFY1 | c.2045C>A p.S682Y (on ENST00000341657 / NM_001330063.2; = p.S683Y on NM_016376.5) | Missense Mutation (SNP) | VAF 21/299 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100492920; called by muse, mutect2
- ANKFY1 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.702); catalogued as COSV58922209; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1413777168, COSV99783895; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7490G>A p.G2497E | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99783899; called by muse, mutect2
- ANKLE1 | c.883G>A p.A295T (on ENST00000394458; = p.A241T on NM_152363.6) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs1232998448, COSV63921569; called by muse, mutect2
- ANKLE2 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1277337025, COSV61710676; called by muse, mutect2, varscan2
- ANKMY1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.214); catalogued as rs373523989; called by muse, mutect2, varscan2
- ANKRD10 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV57445286; called by muse, mutect2, varscan2
- ANKRD11 | c.5756C>T p.A1919V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as rs773848887, COSV56370607; called by muse, mutect2, varscan2
- ANKRD11 | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV56360869; called by muse, mutect2, varscan2
- ANKRD26 | c.1110del p.E371Kfs*12 | Frame Shift Del (DEL) | VAF 14/97 reads (14%) | catalogued as rs775948884, COSV65797837; called by mutect2, pindel, varscan2
- ANKRD27 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV60135609; called by muse, varscan2
- ANKRD28 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs779113898, COSV67516906; called by muse, mutect2, varscan2
- ANKRD30A | c.3665C>A p.A1222D (on ENST00000611781; = p.A1166D on NM_052997.2) | Missense Mutation (SNP) | VAF 81/224 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV64619797; called by muse, mutect2, varscan2
- ANKRD40 | c.1030T>G p.F344V | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.074); catalogued as COSV53328330; called by muse, mutect2, varscan2
- ANKRD40 | c.294A>T p.E98D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as rs199734034; called by muse, mutect2, varscan2
- ANKRD42 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 128/440 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV52618066; called by muse, mutect2, varscan2
- ANKRD44 | c.917G>A p.G306D | Missense Mutation (SNP) | VAF 71/220 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56564805; called by muse, mutect2, varscan2
- ANKRD50 | c.3674G>A p.R1225H | Missense Mutation (SNP) | VAF 55/552 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.405); catalogued as rs373610764; called by muse, mutect2, varscan2
- ANKRD50 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753155406, COSV72386246; called by muse, mutect2, varscan2
- ANKRD53 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs553903679, COSV55539050; called by muse, mutect2, varscan2
- ANKRD55 | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs1187629540, COSV61946699; called by muse, mutect2, varscan2
- ANKS1A | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 81/260 reads (31%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.993); catalogued as rs144409160; called by muse, mutect2, varscan2
- ANKS1A | c.2816C>T p.S939F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV64464244; called by muse, mutect2, varscan2
- ANKS3 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1157096117, COSV58511527; called by muse, mutect2, varscan2
- ANKS6 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs141766991, COSV62048761; called by muse, mutect2, varscan2
- ANKS6 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 55/134 reads (41%) | catalogued as rs1333301505, COSV62049982; called by muse, mutect2, varscan2
- ANO7 | c.2017C>T p.R673W (on ENST00000274979; = p.R619W on NM_001370694.2) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs189777701, COSV51478662; called by muse, mutect2, varscan2
- ANO8 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs539903938, COSV50197978; called by muse, mutect2, varscan2
- ANOS1 | c.1984+1G>T p.X662_splice | Splice Site (SNP) | VAF 4/41 reads (10%) | catalogued as CS149879, COSV99391153; called by muse, mutect2, varscan2
- ANOS1 | c.1531T>C p.S511P | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99391154; called by muse, mutect2, varscan2
- ANTXR1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 67/246 reads (27%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.998); catalogued as rs778487700, COSV58010465, COSV58020941; called by muse, varscan2
- ANTXR2 | c.827C>A p.S276Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55017708, COSV55020671; called by muse, mutect2, varscan2
- ANXA3 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs181568024; called by muse, mutect2, varscan2
- ANXA6 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62908190; called by muse, mutect2, varscan2
- ANXA6 | c.1496G>A p.R499K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV62908197; called by muse, mutect2, varscan2
- AP002748.5 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377159794; called by muse, mutect2, varscan2
- AP1S3 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367791503; called by muse, mutect2, varscan2
- AP4B1 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 62/231 reads (27%) | catalogued as rs762612591, COSV56723465, COSV56726282; called by muse, mutect2, varscan2
- APBA1 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs201072152, COSV55221103; called by muse, mutect2, varscan2
- APBA2 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs767649646, COSV68793175; called by muse, mutect2, varscan2
- APC | c.2248C>T p.P750S | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99969028; called by muse, mutect2
- APC | c.4354G>A p.V1452I | Missense Mutation (SNP) | VAF 77/213 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs1172454959, COSV57358218, COSV57361835; called by muse, mutect2, varscan2
- APCDD1 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100789994; called by muse, mutect2
- APCS | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 52/326 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV54819122, COSV99661251; called by muse, mutect2, varscan2
- APEH | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as rs369269341; called by muse, varscan2
- APEX2 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66624446; called by muse, mutect2, varscan2
- APOBR | c.3225G>A p.M1075I (on ENST00000431282; = p.M1084I on NM_018690.4) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV60493696; called by muse, mutect2, varscan2
- APPL1 | c.415+1G>A p.X139_splice | Splice Site (SNP) | VAF 8/56 reads (14%) | catalogued as COSV55703305; called by muse, mutect2, varscan2
- APTX | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 79/292 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1355291424, COSV58930347; called by muse, mutect2, varscan2
- AQP11 | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV57993155; called by muse, mutect2, varscan2
- AQP8 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780774514, COSV54843977; called by muse, mutect2, varscan2
- AQR | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 18/480 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441763801, COSV50033838; called by muse, mutect2
- ARAF | c.865A>C p.K289Q | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.449); catalogued as COSV51693021, COSV51695101; called by muse, mutect2, varscan2
- ARAP1 | c.3063G>T p.E1021D (on ENST00000393609 / NM_001040118.2; = p.E776D on NM_015242.4) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.401); catalogued as COSV61994629; called by muse, mutect2, varscan2
- AREL1 | c.1175C>A p.P392H | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as COSV100707629; called by muse, mutect2
- ARFGEF1 | c.4043G>A p.R1348H | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250558374, COSV51604057; called by muse, mutect2, varscan2
- ARFGEF2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs778834589, COSV64211088; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARFGEF2 | c.2557C>T p.R853W | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64214823; called by muse, mutect2, varscan2
- ARFIP1 | c.922C>T p.R308C (on ENST00000353617 / NM_001287432.1; = p.R276C on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367792760; called by muse, mutect2, varscan2
- ARHGAP12 | c.914G>T p.S305I | Missense Mutation (SNP) | VAF 84/240 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs1158329745, COSV60966017; called by muse, varscan2
- ARHGAP18 | c.621G>T p.E207D | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as COSV100936350; called by muse, mutect2
- ARHGAP22 | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV50980455; called by muse, mutect2, varscan2
- ARHGAP28 | c.511G>A p.V171I (on ENST00000383472 / NM_001366230.1; = p.V12I on NM_001010000.3) | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99151154; called by muse, mutect2
- ARHGAP32 | c.6037C>T p.R2013C (on ENST00000310343 / NM_001378025.1; = p.R1664C on NM_014715.4) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as rs781495977, COSV59849876; called by muse, mutect2, varscan2
- ARHGAP33 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1300473221, COSV50156555; called by muse, mutect2, varscan2
- ARHGAP33 | c.2552C>T p.A851V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs537289034, COSV50156769; called by muse, mutect2, varscan2
- ARHGAP35 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 65/188 reads (35%) | catalogued as COSV68334058; called by muse, mutect2, varscan2
- ARHGAP36 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 100/307 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370750175, COSV52271370; called by muse, mutect2, varscan2
- ARHGAP36 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 314/1165 reads (27%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.909); catalogued as COSV52271389; called by muse, mutect2, varscan2
- ARHGAP44 | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1341782042, COSV52401655; called by muse, mutect2, varscan2
- ARHGEF1 | c.2253G>T p.W751C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61529478; called by muse, mutect2, varscan2
- ARHGEF10 | c.3109G>A p.A1037T (on ENST00000398564; = p.A1012T on NM_014629.4) | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs754597393, COSV100035016; called by muse, mutect2, varscan2
- ARHGEF11 | c.2768C>T p.A923V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1420230862, COSV59356893; called by muse, mutect2, varscan2
- ARHGEF12 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 106/335 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746485355, COSV63105378; called by muse, mutect2, varscan2
- ARHGEF15 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs376034940, COSV62725688; called by mutect2, varscan2
- ARHGEF15 | c.2227G>T p.G743C | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV62726354; called by muse, mutect2, varscan2
- ARHGEF2 | c.2584G>A p.A862T (on ENST00000361247 / NM_001162383.2; = p.A834T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs759637676, COSV100560822; called by muse, mutect2
- ARHGEF2 | c.1451C>T p.A484V (on ENST00000361247 / NM_001162383.2; = p.A456V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs576936245, COSV58106878, COSV58116737; called by muse, mutect2, varscan2
- ARHGEF26 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.017); catalogued as COSV62851485; called by muse, mutect2, varscan2
- ARHGEF39 | c.904C>T p.L302= | Splice Region (SNP) | VAF 21/57 reads (37%) | catalogued as COSV58398326; called by muse, mutect2, varscan2
- ARHGEF40 | c.2611G>A p.A871T | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV53883947; called by muse, mutect2, varscan2
- ARHGEF6 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 57/376 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV51695673; called by muse, mutect2, varscan2
- ARID2 | c.2591C>T p.A864V | Missense Mutation (SNP) | VAF 104/347 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.985); catalogued as COSV57613562; called by muse, varscan2
- ARID2 | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 101/402 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.14); catalogued as rs944136578, COSV57613570; called by muse, varscan2
- ARID2 | c.3913C>T p.P1305S | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs61925814, COSV57613579; called by muse, mutect2, varscan2
- ARID2 | c.5219C>T p.A1740V | Missense Mutation (SNP) | VAF 93/258 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57613589; called by muse, mutect2, varscan2
- ARL15 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.359); catalogued as rs370435144, COSV72292565; called by muse, mutect2, varscan2
- ARMC4 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs781516128, COSV59472756; called by muse, mutect2, varscan2
- ARMC5 | c.1127G>A p.G376D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV51659658; called by muse, mutect2, varscan2
- ARMC9 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.073); catalogued as rs781051576, COSV63023275; called by muse, mutect2, varscan2
- ARMCX2 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 102/309 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs782665063, COSV57529938; called by muse, mutect2, varscan2
- ARMCX2 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as COSV57531082; called by muse, mutect2, varscan2
- ARNTL | c.907G>A p.E303K (on ENST00000403290 / NM_001297719.2; = p.E302K on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs773491224, COSV100724712, COSV62986216; called by muse, varscan2
- ARRDC3 | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99475350; called by muse, mutect2, varscan2
- ARSG | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 16/297 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1214710312, COSV50929925; called by muse, mutect2
- ASAH2 | c.148dup p.S50Ffs*61 | Frame Shift Ins (INS) | VAF 36/120 reads (30%) | catalogued as rs772181094; called by mutect2, varscan2
- ASB11 | c.369C>T p.H123= | Splice Region (SNP) | VAF 16/112 reads (14%) | catalogued as rs181045050, COSV60356499; called by muse, mutect2, varscan2
- ASB12 | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62857655; called by muse, mutect2, varscan2
- ASGR1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as rs1174966305, COSV52649110; called by muse, mutect2, varscan2
- ASH1L | c.5414G>A p.R1805H | Missense Mutation (SNP) | VAF 50/642 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.375); catalogued as rs757302359, COSV100853525, COSV64214797; called by muse, mutect2
- ASH1L | c.2491C>T p.P831S | Missense Mutation (SNP) | VAF 147/780 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as rs978063094, COSV64213139; called by muse, mutect2, varscan2
- ASH1L | c.1941C>A p.S647R | Missense Mutation (SNP) | VAF 38/476 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.293); catalogued as COSV100853526; called by muse, mutect2
- ASMTL | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV101187837; called by muse, mutect2
- ASNSD1 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs753403228, COSV53623167, COSV99641395; called by muse, mutect2, varscan2
- ASPM | c.9923G>A p.R3308H | Missense Mutation (SNP) | VAF 76/424 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs201362977, COSV54127071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASPM | c.7632G>A p.M2544I | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as COSV54138893; called by muse, mutect2
- ASPM | c.7256G>T p.R2419I | Missense Mutation (SNP) | VAF 15/317 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99660789; called by muse, mutect2
- ASPM | c.5303G>A p.R1768Q | Missense Mutation (SNP) | VAF 30/416 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs781557550, COSV99660791; called by muse, mutect2
- ASPM | c.4369C>T p.H1457Y | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.053); catalogued as COSV54137753; called by muse, varscan2
- ASPM | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 86/472 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs779965746, COSV54137762, COSV99659336; called by muse, mutect2, varscan2
- ASPM | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 29/237 reads (12%) | catalogued as COSV54137772; called by muse, mutect2, varscan2
- ASTE1 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 79/248 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1308492071, COSV53908986; called by muse, mutect2, varscan2
- ASTL | c.282G>A p.W94* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV60905273; called by muse, mutect2
- ASTN2 | c.2658G>T p.K886N (on ENST00000313400 / NM_001365069.1; = p.K835N on NM_014010.5) | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV57814530; called by muse, mutect2, varscan2
- ASXL1 | c.4078C>T p.P1360S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as rs1318861266, COSV60121073; called by muse, mutect2, varscan2
- ASXL1 | c.4471C>T p.Q1491* | Nonsense Mutation (SNP) | VAF 23/75 reads (31%) | catalogued as COSV60121082; called by muse, mutect2, varscan2
- ASXL3 | c.1320G>T p.E440D | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.588); catalogued as COSV99325738; called by muse, mutect2
- ATAD2 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs763753239, COSV54881193; called by muse, mutect2, varscan2
- ATAD2B | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53204714; called by muse, mutect2, varscan2
- ATAD2B | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99478116; called by muse, mutect2
- ATF1 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.388); catalogued as COSV50395815; called by muse, mutect2, varscan2
- ATF6 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 48/852 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.94); catalogued as rs1264613262, COSV100909332; called by muse, mutect2
- ATG16L1 | c.1262C>T p.A421V (on ENST00000392017 / NM_030803.7; = p.A402V on NM_017974.4) | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.756); catalogued as rs751543614, COSV61465941; called by muse, mutect2, varscan2
- ATG2A | c.5767G>A p.A1923T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755353803, COSV63475756; called by muse, mutect2, varscan2
- ATL1 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV63296383; called by muse, mutect2, varscan2
- ATM | c.950A>G p.D317G | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53744162; called by muse, mutect2, varscan2
- ATP10A | c.4489C>T p.R1497W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as rs201645433, COSV63523337; called by mutect2, varscan2
- ATP10A | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV63523344; called by muse, mutect2, varscan2
- ATP10B | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs376276340; called by muse, mutect2, varscan2
- ATP10B | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1054269099, COSV58777732; called by muse, mutect2, varscan2
- ATP10D | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 34/133 reads (26%) | catalogued as rs1243544755, COSV56712652; called by muse, mutect2, varscan2
- ATP10D | c.3528G>A p.M1176I | Missense Mutation (SNP) | VAF 163/435 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56712660; called by muse, mutect2, varscan2
- ATP11C | c.3065C>T p.T1022M | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750778379, COSV59573103; called by muse, mutect2, varscan2
- ATP12A | c.342del p.F115Sfs*28 | Frame Shift Del (DEL) | VAF 165/691 reads (24%) | catalogued as rs35191129; called by mutect2, pindel, varscan2
- ATP13A4 | c.1667C>T p.T556I | Missense Mutation (SNP) | VAF 119/404 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV55074642; called by muse, mutect2, varscan2
- ATP1A2 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV63405724; called by muse, mutect2, varscan2
- ATP1A2 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV63405728; called by muse, mutect2, varscan2
- ATP1A4 | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 44/331 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.515); catalogued as COSV63628305; called by muse, mutect2, varscan2
- ATP1B2 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs756280593, COSV51516577; called by muse, mutect2, varscan2
- ATP2A2 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs886048953, COSV57875184; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B3 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV54859884; called by mutect2, varscan2
- ATP4A | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 75/244 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1472277634, COSV52871487; called by muse, mutect2, varscan2
- ATP6V0A1 | c.117C>T p.D39= | Splice Region (SNP) | VAF 60/386 reads (16%) | catalogued as rs372616123; called by muse, mutect2, varscan2
- ATP6V0A2 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.346); catalogued as COSV57751968; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.079); catalogued as rs776966607, COSV59479719; called by muse, varscan2
- ATP6V0D1 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as rs34389524; called by muse, mutect2, varscan2
- ATP6V0D2 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs776545949, COSV53417519; called by muse, mutect2, varscan2
- ATP6V0E2 | c.230G>A p.R77H (on ENST00000425642; = p.R126H on NM_145230.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as rs765329489, COSV70416394; called by muse, mutect2, varscan2
- ATP6V1B2 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as COSV99369517; called by muse, mutect2
- ATP6V1G2 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 119/374 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.529); catalogued as rs771599164, COSV58214808; called by muse, mutect2, varscan2
- ATP6V1G2 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 39/136 reads (29%) | catalogued as COSV58215129; called by muse, mutect2, varscan2
- ATP6V1H | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 105/267 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs776045554, COSV62220155; called by muse, mutect2, varscan2
- ATP7A | c.3104C>T p.A1035V | Missense Mutation (SNP) | VAF 119/311 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1569550144, COSV58453043; called by muse, mutect2, varscan2
- ATP7A | c.3628G>T p.G1210C | Missense Mutation (SNP) | VAF 24/492 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100431286; called by muse, mutect2
- ATP7B | c.2479C>T p.R827W | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as rs539585071, CM118180, COSV54435476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8A1 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as rs372573029; called by muse, mutect2, varscan2
- ATP8A2 | c.3272C>T p.A1091V | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.434); catalogued as rs199725711, COSV99681789; called by muse, mutect2, varscan2
- ATP8B2 | c.1603G>A p.A535T (on ENST00000672630; = p.A502T on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763575003, COSV59244932, COSV59247692; called by muse, mutect2, varscan2
- ATP8B4 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 102/379 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs777545139, COSV52712160; called by muse, mutect2, varscan2
- ATP9A | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 14/260 reads (5%) | catalogued as rs1161132652, COSV100124742; called by muse, mutect2
- ATP9A | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as rs867929578, COSV58764017; called by muse, mutect2, varscan2
- ATP9B | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.123); catalogued as COSV56960371; called by muse, varscan2
- ATP9B | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781448227, COSV56960384; called by muse, mutect2, varscan2
- ATR | c.7792C>T p.R2598* | Nonsense Mutation (SNP) | VAF 42/140 reads (30%) | catalogued as COSV53817531; called by muse, mutect2, varscan2
- ATRIP | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs919387242, COSV57178738; called by muse, mutect2, varscan2
- ATRN | c.2975C>T p.T992I | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53533412; called by muse, mutect2, varscan2
- ATRN | c.3493T>C p.F1165L | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV99497513; called by muse, mutect2
- ATRNL1 | c.3998C>T p.A1333V | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV58112468; called by muse, mutect2, varscan2
- ATRX | c.2741C>T p.A914V | Missense Mutation (SNP) | VAF 191/643 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV64882637; called by muse, mutect2, varscan2
- ATXN1 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV55229669; called by muse, mutect2, varscan2
- ATXN1 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs771629323, COSV55229679; called by muse, mutect2
- ATXN2 | c.3308C>T p.A1103V (on ENST00000550104; = p.A943V on NM_002973.4) | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.119); catalogued as rs1287322286, COSV66483349, COSV66485298; called by muse, mutect2
- ATXN2L | c.2650C>T p.P884S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.257); catalogued as COSV57378337; called by muse, mutect2, varscan2
- AVIL | c.1715G>T p.S572I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV99142499; called by muse, mutect2
- AWAT2 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs180949354, COSV52144204; called by muse, mutect2, varscan2
- AXL | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.385); catalogued as COSV56574078; called by muse, mutect2, varscan2
- B3GALNT1 | c.462C>A p.N154K | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs1425147283, COSV57581120; called by muse, mutect2, varscan2
- B3GALNT2 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 60/338 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as rs755184356, COSV64004547; called by muse, mutect2, varscan2
- B3GNT5 | c.738G>A p.W246* | Nonsense Mutation (SNP) | VAF 61/163 reads (37%) | catalogued as COSV58476895; called by muse, mutect2, varscan2
- B4GALT6 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV52704973; called by muse, mutect2, varscan2
- BABAM1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.234); catalogued as rs1459959881, COSV63921566; called by mutect2, varscan2
- BACE1 | c.1003A>G p.T335A | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV57286259; called by muse, mutect2, varscan2
- BACH1 | c.488G>T p.R163M | Missense Mutation (SNP) | VAF 106/344 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as COSV54520938, COSV99727971; called by muse, mutect2, varscan2
- BACH1 | c.773G>T p.R258M | Missense Mutation (SNP) | VAF 28/321 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99728464; called by muse, mutect2
- BAG6 | c.2027C>T p.A676V (on ENST00000676571; = p.A629V on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1290462845, COSV52990296; called by muse, mutect2
- BAP1 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56240125; called by muse, mutect2, varscan2
- BARD1 | c.1317C>T p.G439= | Splice Region (SNP) | VAF 31/179 reads (17%) | catalogued as rs369986649; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- BAZ2A | c.5221C>T p.R1741C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs777759132, COSV51635483; called by muse, mutect2, varscan2
- BBOX1 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV99589855; called by muse, mutect2
- BBS7 | c.1447G>A p.V483I | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.175); catalogued as COSV99145007; called by muse, mutect2, varscan2
- BBS9 | c.2531C>T p.T844I (on ENST00000242067 / NM_001348036.1; = p.T804I on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.033); catalogued as COSV54185325; called by muse, mutect2, varscan2
- BBX | c.718C>A p.R240S | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.055); catalogued as COSV57893826; called by muse, mutect2, varscan2
- BCAM | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs555998939, COSV54304628; called by muse, mutect2, varscan2
- BCAM | c.397G>A p.G133S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV99538841; called by muse, mutect2
- BCAN | c.638T>C p.V213A | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV61259298; called by muse, mutect2, varscan2
- BCAN | c.1256C>A p.S419Y | Missense Mutation (SNP) | VAF 43/285 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as COSV61258652, COSV61259320; called by muse, mutect2, varscan2
- BCDIN3D | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV61702822; called by muse, mutect2, varscan2
- BCHE | c.92A>G p.D31G | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs1334341809, COSV52261805; called by muse, mutect2, varscan2
- BCKDK | c.1214G>A p.G405D | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as COSV54891413, COSV54892124; called by muse, mutect2, varscan2
- BCL6B | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.872); catalogued as rs920478239, COSV53430001; called by muse, mutect2, varscan2
- BCL7C | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs138503357; called by muse, mutect2, varscan2
- BCL9 | c.3055C>T p.P1019S | Missense Mutation (SNP) | VAF 115/600 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52349638; called by muse, mutect2, varscan2
- BCL9L | c.1741C>T p.R581W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV52687125, COSV99419733; called by muse, mutect2, varscan2
- BCOR | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.352); catalogued as rs772165033, COSV60702882; called by muse, mutect2, varscan2
- BDP1 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV62434357; called by muse, mutect2, varscan2
- BDP1 | c.599+1G>A p.X200_splice | Splice Site (SNP) | VAF 58/191 reads (30%) | catalogued as rs771223431, COSV62434364; called by muse, mutect2, varscan2
- BDP1 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751018376, COSV62430327; called by muse, mutect2, varscan2
- BEND2 | c.2016G>A p.M672I | Missense Mutation (SNP) | VAF 40/320 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV66216071, COSV66217100; called by muse, mutect2, varscan2
- BEST3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56995869; called by muse, mutect2, varscan2
- BEX4 | c.125A>G p.E42G | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as COSV65516220; called by muse, mutect2, varscan2
- BEX5 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 72/610 reads (12%) | catalogued as COSV61328963; called by muse, mutect2, varscan2
- BFSP2 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as rs1224719314, COSV56591649; called by muse, mutect2, varscan2
- BHLHE40 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs773058967, COSV56576441; called by muse, mutect2, varscan2
- BICDL1 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as rs368843219; called by muse, mutect2, varscan2
- BID | c.362-1G>T p.X121_splice (on ENST00000317361 / NM_197966.2; = p.X75_splice on NM_001196.4) | Splice Site (SNP) | VAF 4/9 reads (44%) | catalogued as COSV100433825; called by muse, mutect2
- BIRC6 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1242929526, COSV70205022; called by muse, mutect2, varscan2
- BIRC6 | c.2504G>A p.R835Q | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.642); catalogued as rs1022274342, COSV101429309, COSV70205028; called by muse, mutect2, varscan2
- BIRC6 | c.11801G>A p.R3934H | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs766431375, COSV70198526; called by muse, mutect2, varscan2
- BIRC6 | c.12712G>A p.A4238T | Missense Mutation (SNP) | VAF 88/261 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.413); catalogued as COSV70205037; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2407C>T p.Q803* | Nonsense Mutation (SNP) | VAF 84/218 reads (39%) | catalogued as rs1480813777, COSV63247195; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3817C>T p.R1273W | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770975661, CM065154, COSV63243835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4397G>A p.S1466N | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1417435380, COSV63247205; called by muse, mutect2, varscan2
- BLM | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV61927072; called by muse, varscan2
- BLM | c.2720C>T p.T907M | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs367953471; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP2K | c.2834G>A p.S945N | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV55011714; called by muse, mutect2, varscan2
- BMP5 | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV63705218, COSV63706208; called by muse, mutect2, varscan2
- BMP5 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.895); catalogued as COSV63702143; called by muse, mutect2, varscan2
- BMP7 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749392235, COSV67782449; called by muse, mutect2, varscan2
- BNC2 | c.1171A>G p.T391A | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.121); catalogued as COSV66156315; called by muse, mutect2, varscan2
- BOC | c.2737G>A p.G913S | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs748607085, COSV56357308; called by muse, mutect2, varscan2
- BOD1L1 | c.7613A>G p.D2538G | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV50056372; called by muse, mutect2, varscan2
- BOD1L1 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV50056927; called by muse, mutect2, varscan2
- BPHL | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV100984519; called by muse, mutect2
- BPIFB1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 75/215 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV53608620; called by muse, mutect2, varscan2
- BPIFB4 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs143050216; called by muse, mutect2, varscan2
- BRCA2 | c.6058G>A p.E2020K | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs80358842, CM101422, COSV66450746; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.7625C>T p.T2542M | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs80358989, COSV66461826; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BRCC3 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 99/280 reads (35%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); catalogued as COSV57464027; called by muse, mutect2, varscan2
- BRD2 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 102/268 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as rs771459465, COSV66374414; called by muse, mutect2, varscan2
- BRD9 | c.1580C>T p.T527M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs1356964265, COSV60246591; called by muse, mutect2, varscan2
- BRF2 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751368381, COSV55105035; called by muse, mutect2, varscan2
- BRINP3 | c.1792C>T p.R598W | Missense Mutation (SNP) | VAF 152/814 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as rs772136142, COSV66539636; called by muse, varscan2
- BRIP1 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 147/451 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs587780235, CM1210625, COSV52004661; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRPF1 | c.2201G>A p.R734H | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs1359599082, COSV57407553; called by muse, mutect2, varscan2
- BRPF3 | c.2561del p.P854Rfs*6 | Frame Shift Del (DEL) | VAF 20/203 reads (10%) | catalogued as rs1413008697, COSV60208966; called by mutect2, pindel, varscan2
- BRS3 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs1158671400, COSV65711276; called by muse, varscan2
- BRWD1 | c.6542C>T p.T2181M | Missense Mutation (SNP) | VAF 73/260 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs148068634; called by muse, mutect2, varscan2
- BRWD1 | c.6281G>A p.R2094H | Missense Mutation (SNP) | VAF 144/486 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.732); catalogued as rs766937547, COSV60902182; called by muse, varscan2
- BRWD1 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV60902199; called by muse, varscan2
- BSPRY | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as rs1016505275, COSV65243484; called by muse, mutect2, varscan2
- BTBD3 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); catalogued as rs777556357, COSV54779698; called by mutect2, varscan2
- BTBD3 | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs181823752; called by muse, mutect2, varscan2
- BTBD9 | c.1371G>T p.W457C | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58435137; called by muse, mutect2, varscan2
- BTNL8 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 181/602 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs748602705, COSV51460359; called by muse, mutect2, varscan2
- BUB3 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 14/248 reads (6%) | catalogued as rs866193666, COSV64363766; called by muse, mutect2
- BUD13 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99496632; called by muse, mutect2
- BUD31 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52863283; called by muse, varscan2
- C10orf71 | c.1050del p.C351Afs*48 | Frame Shift Del (DEL) | VAF 44/167 reads (26%) | catalogued as COSV60509047; called by pindel, varscan2
- C10orf71 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as COSV60512339; called by muse, varscan2
- C10orf88 | c.401del p.N134Ifs*2 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | catalogued as rs751388819; called by mutect2, varscan2
- C12orf40 | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 92/369 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV61137215; called by muse, mutect2, varscan2
- C12orf45 | c.551dup p.K185Efs*5 | Frame Shift Ins (INS) | VAF 22/100 reads (22%) | catalogued as rs777032057; called by mutect2, varscan2
- C12orf50 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775915157, COSV100072378; called by muse, mutect2
- C12orf56 | c.1075G>T p.A359S (on ENST00000543942 / NM_001170633.2; = p.A199S on NM_001099676.3) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61489813; called by muse, mutect2, varscan2
- C16orf71 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1256393239, COSV54794802; called by muse, mutect2, varscan2
- C17orf75 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.247); catalogued as COSV56754052; called by muse, mutect2
- C17orf98 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs369883104; called by muse, mutect2, varscan2
- C18orf54 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs150796364, COSV55619281; called by muse, mutect2, varscan2
- C1GALT1C1L | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as rs754668514; called by muse, mutect2
- C1QTNF1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.197); catalogued as rs776839033, COSV59260951; called by muse, varscan2
- C1QTNF3 | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 23/175 reads (13%) | catalogued as rs1173584671, COSV51467655; called by muse, mutect2, varscan2
- C1QTNF9B | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 44/217 reads (20%) | catalogued as rs370739126; called by muse, mutect2, varscan2
- C1orf100 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs754781063, COSV57373117; called by muse, mutect2, varscan2
- C1orf112 | c.2510C>T p.A837V | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs763182857, COSV53678044; called by muse, mutect2
- C1orf116 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs867497260, COSV63944638; called by muse, mutect2, varscan2
- C1orf116 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs750528994, COSV63944643; called by muse, mutect2, varscan2
- C1orf127 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.991); catalogued as COSV100983499; called by muse, mutect2
- C1orf198 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 26/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100793456; called by muse, mutect2
- C1orf226 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 10/117 reads (9%) | catalogued as COSV63396785; called by muse, mutect2
- C20orf27 | c.416G>A p.R139H (on ENST00000379772 / NM_001258429.2; = p.R164H on NM_001039140.3) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs746711207, COSV53925257; called by muse, mutect2, varscan2
- C2CD5 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 131/377 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs1404837859, COSV61725250; called by muse, mutect2, varscan2
- C2CD6 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.141); catalogued as COSV53799937; called by muse, mutect2, varscan2
- C2orf16 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.136); catalogued as COSV68843029; called by muse, mutect2, varscan2
- C2orf78 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV101281009; called by muse, mutect2
- C3orf70 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.613); catalogued as COSV58590371; called by muse, mutect2, varscan2
- C4BPB | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV99700070; called by muse, mutect2, varscan2
- C5orf24 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57542656; called by muse, mutect2, varscan2
- C5orf46 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV59154576; called by muse, mutect2, varscan2
- C6 | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54708544; called by muse, mutect2, varscan2
- C7 | c.1495G>T p.V499F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as COSV57480192; called by mutect2, varscan2
- C8A | c.1420G>T p.G474W | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63486227; called by muse, mutect2, varscan2
- C8B | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as COSV64779440; called by muse, mutect2, varscan2
- C9orf131 | c.2383C>T p.R795W | Missense Mutation (SNP) | VAF 192/595 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as rs775963999, COSV56613942; called by muse, mutect2, varscan2
- C9orf43 | c.680C>T p.T227I | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV55914010; called by muse, varscan2
- C9orf43 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 108/335 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs755891099, COSV55912321; called by muse, varscan2
- CA5B | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201165361, COSV59416347; called by muse, mutect2, varscan2
- CA7 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV58157207; called by muse, mutect2, varscan2
- CABIN1 | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 92/253 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54088357; called by muse, mutect2, varscan2
- CABIN1 | c.4124G>A p.S1375N | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV54088384; called by muse, mutect2, varscan2
- CABLES2 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV54156545; called by muse, mutect2, varscan2
- CABP1 | c.764G>A p.R255H (on ENST00000316803 / NM_001033677.1; = p.R52H on NM_004276.5) | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747880479, COSV56458162; called by muse, mutect2, varscan2
- CABP4 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1031406409, COSV56887942; called by muse, mutect2, varscan2
- CABS1 | c.465G>T p.E155D | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56734419; called by muse, mutect2, varscan2
- CACNA1A | c.2000G>A p.G667D | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64211159; called by muse, mutect2, varscan2
- CACNA1D | c.5984C>T p.P1995L (on ENST00000350061 / NM_001128840.3; = p.P2015L on NM_000720.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.049); catalogued as rs780303719, COSV55463165, COSV99860879; called by muse, mutect2, varscan2
- CACNA1E | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100701577, COSV62391937, COSV62405729; called by muse, mutect2, varscan2
- CACNA1E | c.3812G>A p.R1271H | Missense Mutation (SNP) | VAF 101/492 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62416471; called by muse, mutect2, varscan2
- CACNA1E | c.5053C>T p.P1685S | Missense Mutation (SNP) | VAF 87/378 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as COSV62387981; called by muse, varscan2
- CACNA1E | c.5083G>A p.G1695S | Missense Mutation (SNP) | VAF 70/425 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1160971846, COSV62381053; called by muse, varscan2
- CACNA1E | c.6191G>A p.R2064H (on ENST00000367573 / NM_001205293.3; = p.R2021H on NM_000721.4) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.747); catalogued as rs779562850, COSV62416498; called by muse, mutect2, varscan2
- CACNA1E | c.6247C>T p.R2083W (on ENST00000367573 / NM_001205293.3; = p.R2040W on NM_000721.4) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1337866196, COSV100702838, COSV62389153; called by muse, mutect2
- CACNA2D3 | c.1470C>T p.T490= | Splice Region (SNP) | VAF 73/204 reads (36%) | catalogued as rs775379312, COSV55516775; called by muse, mutect2, varscan2
- CACNA2D4 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.912); catalogued as rs954675574, COSV54957789; called by muse, mutect2
- CACNB2 | c.845G>A p.R282Q (on ENST00000324631 / NM_201596.3; = p.R227Q on NM_000724.4) | Missense Mutation (SNP) | VAF 121/320 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56644915; called by muse, mutect2, varscan2
- CACNB3 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781661766, COSV56398844; called by muse, mutect2, varscan2
- CACNG6 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as rs147457475; called by muse, mutect2, varscan2
- CACYBP | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.98); catalogued as rs1020068190; called by muse, mutect2
- CAD | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV53031330; called by muse, mutect2, varscan2
- CADPS | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761109512, COSV51900360; called by muse, mutect2, varscan2
- CADPS2 | c.3644G>A p.C1215Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.401); catalogued as COSV57383301; called by muse, mutect2, varscan2
- CADPS2 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | catalogued as rs1293595108, COSV57380135; called by muse, mutect2, varscan2
- CALCOCO2 | c.1171C>A p.P391T | Missense Mutation (SNP) | VAF 87/243 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV51953571; called by muse, mutect2, varscan2
- CALM2 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.89); catalogued as COSV55399058; called by muse, mutect2
- CAMK2A | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV62247600; called by muse, mutect2, varscan2
- CAMSAP1 | c.4010G>A p.R1337H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1386838221, COSV56720748; called by muse, mutect2, varscan2
- CAMSAP1 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs557057282, COSV56725807; called by muse, mutect2, varscan2
- CAMTA1 | c.3452C>T p.A1151V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57924013; called by muse, mutect2, varscan2
- CAND2 | c.3535C>T p.R1179C (on ENST00000456430 / NM_001162499.2; = p.R1062C on NM_012298.3) | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768520399, COSV55993986; called by muse, mutect2, varscan2
- CANT1 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100185330; called by mutect2, varscan2
- CAPG | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.809); catalogued as rs768616851, COSV55708695; called by muse, mutect2, varscan2
- CAPN1 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as rs1217528784, COSV54201281; called by muse, mutect2, varscan2
- CAPN2 | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.907); catalogued as COSV54339454, COSV99689363; called by muse, mutect2, varscan2
- CAPN2 | c.729+1G>A p.X243_splice | Splice Site (SNP) | VAF 43/243 reads (18%) | catalogued as rs549405629, COSV54335443; called by muse, mutect2, varscan2
- CAPN2 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs781468603, COSV54339190; called by muse, mutect2, varscan2
- CAPN6 | c.1315C>A p.L439I | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.241); catalogued as COSV60693838; called by muse, mutect2, varscan2
- CAPN7 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1170621390, COSV53777945; called by muse, mutect2, varscan2
- CAPN9 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV55232370, COSV55239783; called by muse, varscan2
- CAPRIN1 | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748363218, COSV100403563, COSV58222179; called by muse, mutect2, varscan2
- CARMIL1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV61523262; called by muse, mutect2, varscan2
- CARMIL3 | c.2399C>T p.A800V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); catalogued as rs774345899, COSV57728187; called by muse, mutect2, varscan2
- CARS1 | c.2061del p.S688Vfs*37 | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | catalogued as rs753057519; called by mutect2, pindel, varscan2
- CASP5 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 132/398 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs761988172, COSV52828789, COSV52829027; called by muse, mutect2
- CASP9 | c.246G>T p.Q82H | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); catalogued as COSV100423882; called by mutect2, varscan2
- CASQ1 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as COSV63624521; called by muse, mutect2
- CASR | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 20/458 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV99949242; called by muse, mutect2
- CATIP | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1203818432, COSV99179586; called by muse, mutect2
- CATSPER3 | c.198del p.F66Lfs*10 | Frame Shift Del (DEL) | VAF 80/236 reads (34%) | catalogued as CM110786; called by mutect2, pindel, varscan2
- CATSPERG | c.2201G>C p.G734A | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV53053073; called by muse, mutect2, varscan2
- CATSPERG | c.3040G>A p.A1014T | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs756023189, COSV53053086; called by muse, mutect2, varscan2
- CAVIN2 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58424350, COSV58425725; called by muse, mutect2, varscan2
- CBFB | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 106/290 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1467426352, COSV51998270; called by muse, mutect2, varscan2
- CBL | c.239G>A p.S80N | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV50643747; called by muse, mutect2
- CBLL2 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 126/376 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as COSV60368352, COSV60369991; called by muse, mutect2, varscan2
- CBLL2 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 152/424 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs766786548, COSV60369842; called by muse, varscan2
- CBLN3 | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1215096629, COSV99249912; called by muse, mutect2
- CBY2 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs1048522766, COSV60118086; called by muse, mutect2, varscan2
- CCAR2 | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs201363003; called by muse, mutect2, varscan2
- CCAR2 | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs776652812, COSV99373898; called by mutect2, varscan2
- CCDC105 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV52964203; called by muse, mutect2, varscan2
- CCDC114 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs751715030, COSV59556314, COSV59558091; called by mutect2, varscan2
- CCDC144A | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as rs577983126, COSV61404658; called by muse, mutect2, varscan2
- CCDC146 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 58/228 reads (25%) | catalogued as rs754079533, COSV53551543; called by muse, varscan2
- CCDC151 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1167009347, COSV62698407; called by muse, mutect2, varscan2
- CCDC171 | c.3549G>T p.E1183D | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV52637988; called by muse, mutect2, varscan2
- CCDC173 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as rs774095741, COSV69573195; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 44/167 reads (26%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC185 | c.734G>T p.S245I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs1390761224, COSV64821789; called by muse, mutect2, varscan2
- CCDC185 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.729); catalogued as rs1050895261, COSV64820780; called by muse, mutect2
- CCDC186 | c.2153G>A p.S718N | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as COSV65162057; called by muse, mutect2, varscan2
- CCDC33 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV100351643; called by muse, mutect2
- CCDC40 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as COSV53904122; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC47 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755476973, COSV56724607; called by muse, varscan2
- CCDC50 | c.1115C>T p.A372V (on ENST00000392455 / NM_178335.3; = p.A196V on NM_174908.4) | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66669542; called by muse, mutect2, varscan2
- CCDC57 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs749318039, COSV58937073; called by muse, varscan2
- CCDC65 | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV57195979; called by muse, mutect2, varscan2
- CCDC80 | c.2184G>T p.E728D | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV52819633; called by muse, mutect2, varscan2
- CCDC80 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs771380755, COSV52814709; called by mutect2, varscan2
- CCDC83 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0.033); catalogued as COSV54704617; called by muse, mutect2, varscan2
- CCDC85A | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101339498; called by mutect2, varscan2
- CCDC88A | c.2821C>T p.R941* | Nonsense Mutation (SNP) | VAF 35/112 reads (31%) | catalogued as COSV55068992; called by muse, mutect2, varscan2
- CCDC88A | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs766205443, COSV55057829; called by muse, mutect2, varscan2
- CCDC88C | c.3829G>A p.A1277T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV66241183; called by muse, mutect2
- CCDC91 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs544457452, COSV60339285; called by muse, mutect2, varscan2
- CCDC92 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as rs1460952697, COSV53019580; called by muse, mutect2
- CCL1 | c.94A>G p.R32G | Missense Mutation (SNP) | VAF 86/296 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as COSV56775615, COSV99861639; called by muse, mutect2, varscan2
- CCL17 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as rs756502125, COSV54665217; called by muse, mutect2, varscan2
- CCL28 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs775586405, COSV63149299; called by muse, mutect2, varscan2
- CCM2 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs781634033, COSV51851107; called by muse, mutect2, varscan2
- CCN2 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV63466993; called by muse, mutect2, varscan2
- CCN4 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51535169; called by muse, mutect2
- CCNA2 | c.1285A>G p.T429A | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as COSV54667849; called by muse, mutect2, varscan2
- CCNB1 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as rs138386021; called by muse, mutect2, varscan2
- CCND2 | c.152T>G p.I51S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54225760; called by muse, mutect2, varscan2
- CCNL1 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs948726021, COSV55818059; called by muse, mutect2, varscan2
- CCNY | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV55190439; called by muse, mutect2, varscan2
- CCPG1 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as rs749167344, COSV60526186; called by muse, mutect2, varscan2
- CCT3 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs138692004, COSV55287654; called by muse, mutect2, varscan2
- CCT5 | c.1061G>A p.G354D | Missense Mutation (SNP) | VAF 157/485 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54725329; called by muse, mutect2, varscan2
- CCT6A | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as rs1330198064, COSV51907494; called by muse, mutect2, varscan2
- CCT8L2 | c.1654dup p.I552Nfs*6 | Frame Shift Ins (INS) | VAF 34/104 reads (33%) | catalogued as rs780034402; called by mutect2, varscan2
- CCT8L2 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs144320279; called by muse, mutect2
- CD101 | c.1048C>T p.L350F | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV56720745; called by muse, mutect2, varscan2
- CD163 | c.2294C>T p.A765V | Missense Mutation (SNP) | VAF 83/348 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63136758; called by muse, mutect2, varscan2
- CD1A | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779636773, COSV56864039; called by muse, mutect2, varscan2
- CD200R1 | c.964C>A p.L322I (on ENST00000471858 / NM_170780.3; = p.L345I on NM_138806.4) | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV99867553; called by muse, mutect2, varscan2
- CD207 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.106); catalogued as rs529039529, COSV69652558; called by muse, mutect2, varscan2
- CD274 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 6/100 reads (6%) | catalogued as rs897885359, COSV101055992; called by muse, mutect2
- CD2BP2 | c.146G>T p.S49I | Missense Mutation (SNP) | VAF 112/345 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59769795; called by muse, mutect2, varscan2
- CD300C | c.166T>G p.W56G | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58171337; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 75/287 reads (26%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD46 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 20/460 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100522703; called by muse, mutect2
- CD5 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV61719042; called by muse, mutect2, varscan2
- CD53 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54762964; called by muse, varscan2
- CD59 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV60919887; called by muse, mutect2, varscan2
- CD86 | c.119G>A p.C40Y (on ENST00000330540 / NM_175862.5; = p.C34Y on NM_006889.4) | Missense Mutation (SNP) | VAF 86/327 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52609951; called by muse, mutect2, varscan2
- CD86 | c.395T>C p.V132A (on ENST00000330540 / NM_175862.5; = p.V126A on NM_006889.4) | Missense Mutation (SNP) | VAF 23/325 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100054083; called by muse, mutect2
- CDC20B | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV57056988; called by muse, mutect2, varscan2
- CDC25C | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs866390878, COSV60399554; called by muse, mutect2, varscan2
- CDC40 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs773612198, COSV57011988; called by muse, mutect2, varscan2
- CDC42BPG | c.2930G>A p.R977H | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs547105991, COSV61349018; called by muse, varscan2
- CDC42BPG | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs761133866, COSV61348987; called by muse, varscan2
- CDC5L | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV65177124; called by muse, mutect2, varscan2
- CDC5L | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs368546991; called by muse, mutect2, varscan2
- CDC73 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 55/437 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs368442389; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDCA5 | c.661A>G p.K221E | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51871113; called by muse, mutect2, varscan2
- CDH10 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV52588361, COSV52595598; called by muse, mutect2, varscan2
- CDH11 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as COSV51775944; called by muse, mutect2, varscan2
- CDH15 | c.1244A>T p.D415V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.327); catalogued as COSV57027356; called by muse, mutect2
- CDH17 | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs755202108, COSV50339118; called by muse, mutect2, varscan2
- CDH18 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as COSV56913618; called by muse, mutect2
- CDH23 | c.6823C>T p.P2275S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56486772; called by muse, mutect2, varscan2
- CDH26 | c.837C>T p.N279= | Splice Region (SNP) | VAF 9/29 reads (31%) | catalogued as rs758453442, COSV54853958; called by muse, mutect2, varscan2
- CDH3 | c.431G>A p.S144N | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV50570307; called by muse, mutect2, varscan2
- CDH5 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs890414077, COSV100439335; called by muse, mutect2
- CDH5 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as rs373144857; called by muse, mutect2, varscan2
- CDH7 | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV59884339; called by muse, mutect2, varscan2
- CDH8 | c.2034G>T p.E678D | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV100183163; called by muse, mutect2
- CDH8 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.026); catalogued as rs866368256, COSV54896712; called by muse, mutect2, varscan2
- CDHR1 | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs765592663, COSV60566084; called by mutect2, varscan2
- CDHR2 | c.836G>T p.S279I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV56144514; called by muse, mutect2, varscan2
- CDHR3 | c.1450C>T p.R484* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as rs368274712; called by muse, mutect2
- CDK12 | c.3022C>T p.R1008W | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71000145; called by muse, mutect2
- CDK13 | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1057000, COSV51706034; called by muse, mutect2, varscan2
- CDK16 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV52092673; called by muse, mutect2, varscan2
- CDK16 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs1415055054, COSV52093757; called by muse, mutect2, varscan2
- CDK8 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67422935; called by muse, mutect2, varscan2
- CDKL5 | c.2783C>T p.T928M | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs951430019, COSV66107411; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CDX1 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140956520, COSV51567579; called by muse, mutect2, varscan2
- CDYL | c.245G>A p.R82Q (on ENST00000328908 / NM_001368125.1; = p.R28Q on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as rs1186573267, COSV59361652; called by muse, mutect2, varscan2
- CDYL | c.724G>A p.G242R (on ENST00000328908 / NM_001368125.1; = p.G188R on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.28); catalogued as rs150926278; called by muse, mutect2, varscan2
- CEACAM18 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as rs775191087, COSV67282189; called by muse, mutect2, varscan2
- CEACAM20 | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100386958; called by muse, mutect2, varscan2
- CEACAM21 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV99494671; called by muse, mutect2
- CEACAM8 | c.62C>T p.T21I | Missense Mutation (SNP) | VAF 145/393 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as COSV54991651; called by muse, mutect2, varscan2
- CEBPZ | c.2885-3del | Splice Region (DEL) | VAF 48/224 reads (21%) | catalogued as rs375852685; called by mutect2, varscan2
- CELF3 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV51885574; called by muse, mutect2, varscan2
- CELF3 | c.1265G>A p.C422Y | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51885583; called by muse, mutect2, varscan2
- CELF3 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1369926945, COSV51885599; called by muse, mutect2, varscan2
- CELF6 | c.1417C>T p.R473W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760379153, COSV54718562; called by muse, mutect2, varscan2
- CELF6 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs769697445, COSV54716803, COSV54718583; called by muse, mutect2, varscan2
- CELSR1 | c.4468G>A p.D1490N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs953345385, COSV53092565, COSV99419148; called by muse, mutect2
- CELSR2 | c.6493C>T p.P2165S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV54778511; called by muse, mutect2, varscan2
- CENPC | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs371671240, COSV56623034; called by muse, mutect2, varscan2
- CENPE | c.4801G>A p.A1601T | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.138); catalogued as COSV54389019; called by muse, mutect2, varscan2
- CENPE | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1390317195, COSV54389038; called by muse, mutect2, varscan2
- CENPI | c.1343G>A p.G448D | Missense Mutation (SNP) | VAF 120/351 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54505932; called by muse, mutect2, varscan2
- CENPJ | c.1204A>G p.T402A | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.057); catalogued as COSV67884152; called by muse, mutect2, varscan2
- CENPL | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61892928; called by muse, mutect2, varscan2
- CEP112 | c.2746C>T p.P916S (on ENST00000392769 / NM_001353127.1; = p.P172S on NM_001037325.3) | Missense Mutation (SNP) | VAF 15/269 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100439346; called by muse, mutect2
- CEP126 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142032267, COSV54826164; called by muse, mutect2, varscan2
- CEP164 | c.3683G>A p.S1228N | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV54045814; called by muse, mutect2, varscan2
- CEP170 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 54/297 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1314069652, COSV60513676; called by muse, mutect2, varscan2
- CEP192 | c.6169C>A p.L2057I | Missense Mutation (SNP) | VAF 47/267 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.397); catalogued as COSV58070087; called by muse, mutect2, varscan2
- CEP250 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs143763293; called by muse, mutect2, varscan2
- CEP250 | c.5524G>A p.A1842T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs747287126, COSV61167906; called by muse, mutect2, varscan2
- CEP290 | c.3215G>A p.R1072Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1298561837, COSV58355431; called by muse, mutect2, varscan2
- CEP350 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1481861560, COSV62486017, COSV62486193; called by muse, mutect2, varscan2
- CEP350 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.185); catalogued as COSV62486068; called by muse, mutect2, varscan2
- CEP350 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 86/408 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149644649; called by muse, mutect2, varscan2
- CEP350 | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 102/489 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV62609117; called by muse, mutect2, varscan2
- CEP350 | c.4292C>T p.T1431M | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs1023426131, COSV62609136; called by muse, mutect2, varscan2
- CEP350 | c.7408C>T p.R2470C | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs778785732, COSV62604980; called by mutect2, varscan2
- CEP350 | c.8291A>G p.K2764R | Missense Mutation (SNP) | VAF 62/335 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.286); catalogued as rs1488643004, COSV62609145; called by muse, mutect2, varscan2
- CEP76 | c.645G>A p.W215* | Nonsense Mutation (SNP) | VAF 64/168 reads (38%) | catalogued as COSV50870023; called by muse, mutect2, varscan2
- CEP83 | c.1657T>C p.Y553H | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.967); catalogued as COSV100353015; called by muse, mutect2
- CEP89 | c.1147C>T p.L383F | Missense Mutation (SNP) | VAF 27/561 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.749); catalogued as COSV99993757; called by muse, mutect2
- CEPT1 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 81/268 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1447517148, COSV64111185; called by muse, mutect2, varscan2
- CES2 | c.1672G>T p.E558* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV57697737; called by muse, mutect2
- CFAP206 | c.1831G>A p.V611I | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV100849667, COSV65810075; called by muse, mutect2, varscan2
- CFAP251 | c.1198G>A p.V400I | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs1046083359, COSV56615382; called by muse, mutect2, varscan2
- CFAP43 | c.2213C>T p.A738V | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV53380904, COSV53382096; called by muse, mutect2, varscan2
- CFAP44 | c.1655C>T p.T552M | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as rs781687661, COSV55609987; called by muse, mutect2, varscan2
- CFAP45 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 81/562 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV63650932; called by muse, mutect2, varscan2
- CFAP46 | c.5533G>T p.G1845W | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as COSV99583730; called by muse, mutect2
- CFAP47 | c.341A>G p.D114G | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV52890943; called by muse, mutect2, varscan2
- CFAP47 | c.4586C>T p.A1529V | Missense Mutation (SNP) | VAF 61/218 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as COSV57974124; called by muse, mutect2, varscan2
- CFAP47 | c.5386G>A p.A1796T | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV57976401; called by muse, mutect2, varscan2
- CFAP53 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.24); catalogued as COSV101275007; called by muse, varscan2
- CFAP61 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.267); catalogued as rs750210901, COSV55629755, COSV55645473; called by muse, mutect2, varscan2
- CFAP65 | c.5249G>T p.R1750I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV58559339, COSV58565862; called by muse, mutect2, varscan2
- CFAP74 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.02); catalogued as COSV54573313; called by muse, mutect2, varscan2
- CFAP91 | c.1186C>T p.L396F | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56342325; called by muse, mutect2, varscan2
- CFAP92 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV54046897; called by muse, mutect2, varscan2
- CFAP97 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs192418727, COSV71712879; called by muse, mutect2, varscan2
- CFDP1 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 123/427 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV52211643; called by muse, mutect2, varscan2
5,652 further variants in this file (3,903 protein-altering or splice-affecting, 1,612 silent, 137 other) are not listed here.
